Gene-level copy-number profile of tumor specimen TCGA-59-2363-01A from TCGA case TCGA-59-2363, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIA; Tumor grade: G3.
Specimen TCGA-59-2363-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.eb5241b3-941e-499b-8753-6a0e2eb474e8.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-59-2363-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 817 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/43ba5df2-215a-4817-9818-7fe91a1a081f

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 25,511; copy number 2: 28,627; copy number 3: 4,520; copy number 4: 869; copy number 5: 127; copy number 6: 138; copy number 8: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-59-2363-01A-01D-0704-01): tumor purity 0.92, ploidy 1.73, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr18:3,571,215–3,656,282, 5 genes: RN7SL39P, AP002472.1, DLGAP1-AS1, DLGAP1-AS2, AP002478.1.
- chr18:51,174,550–51,643,939, 5 genes (within-gene range 0–1): MEX3C, RNU1-46P, LINC01630, SS18L2P2, AC109315.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 269 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:191,949,043–192,194,933, 1 gene, copy number 5 (within-gene range 4–5): TMEFF2.
- chr8:117,794,490–135,742,495, 261 genes, copy number 5–8 (broad region; genes not listed).
- chr8:135,977,329–136,295,232, 2 genes, copy number 5: AC103955.1, AC023781.1.
- chr12:15,001,787–15,348,675, 5 genes, copy number 5 (within-gene range 3–5): LINC01489, RERG, RERG-IT1, RERG-AS1, METTL8P1.

Autosomal genes at a single copy (total copy number 1): 23,119. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
